FM case AD4363 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/c5b17801-50fe-4460-87b6-5528d75689de

Male, 61.9 years: Mesothelioma, NOS (ICD-O-3 9050/3) of the pleura; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
